Somatic mutation profile of tumor specimen MP2PRT-PAVTNV-TBP1-A (aliquot MP2PRT-PAVTNV-TBP1-A-1-0-D-A821-36) from MP2PRT case MP2PRT-PAVTNV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.8 years (673 days).
Specimen MP2PRT-PAVTNV-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a945ddc4-1394-419a-ad2d-d10d831023cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVTNV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVTNV-NB1-A-1-0-D-A821-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ff51a05-509a-4e6c-94cd-0ccb048afc2a

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FNDC1 | c.4486C>T p.R1496W | Missense Mutation (SNP) | VAF 95/660 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.762); catalogued as rs377571503; called by muse, mutect2, varscan2
- LOXHD1 | c.6547G>A p.G2183R (on ENST00000642948; = p.G2121R on NM_144612.7) | Missense Mutation (SNP) | VAF 17/587 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs943633635, COSV56068086; ClinVar: uncertain significance; called by muse, mutect2
- SAMD12 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 14/398 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs1369701058; called by muse, mutect2
- IGHJ4 | c.1_2del p.Y1Lfs*? | Frame Shift Del (DEL) | VAF 24/187 reads (13%) | called by pindel*, varscan2
- DCAF12L1 | c.195C>G p.P65= | Silent (SNP) | VAF 25/533 reads (5%) | catalogued as rs1431901402, COSV64421612; called by muse, mutect2
- MGAT3 | c.1305C>T p.A435= | Silent (SNP) | VAF 30/463 reads (6%) | called by muse, mutect2
